Somatic mutation profile of tumor specimen TCGA-MZ-A7D7-01A (aliquot TCGA-MZ-A7D7-01A-21D-A34J-08) from TCGA case TCGA-MZ-A7D7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 51.9 years (18,974 days).
Specimen TCGA-MZ-A7D7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9c59d34-bd23-4d99-b19c-d24a8611a24a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MZ-A7D7-10A (Blood Derived Normal), aliquot TCGA-MZ-A7D7-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1aa40cb-377c-40e9-9afc-c3f15ce2135d

The open-access MAF lists 158 somatic variants for this specimen: 112 protein-altering or splice-affecting, 41 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 41, Nonsense Mutation 11, Intron 4, Frame Shift Del 4, RNA 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.599del p.N200Ifs*47 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | catalogued as rs1131691011, COSV52677283, COSV52840642, COSV53742336; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.6491C>T p.S2164L (on ENST00000272895 / NM_173076.3; = p.S1846L on NM_015657.3) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.083); catalogued as rs765410981, COSV99787619; called by muse, mutect2, varscan2
- ACTL9 | c.186G>C p.K62N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100185032, COSV100185422, COSV61006097; called by muse, mutect2, varscan2
- ACVR1C | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as COSV99694246; called by muse, mutect2, varscan2
- AKAP9 | c.7621C>T p.Q2541* (on ENST00000359028; = p.Q2517* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV100661745, COSV100661909; called by muse, mutect2, varscan2
- ALPK2 | c.4972G>T p.G1658* | Nonsense Mutation (SNP) | VAF 44/143 reads (31%) | catalogued as COSV100863897; called by muse, mutect2, varscan2
- C6 | c.990A>C p.K330N | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99666156; called by muse, mutect2
- CARMIL2 | c.2582G>A p.R861K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100575903; called by muse, mutect2, varscan2
- CCDC96 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100027721, COSV100027819; called by muse, mutect2, varscan2
- CDH4 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100848175; called by muse, mutect2, varscan2
- CFAP45 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs200089318; called by muse, mutect2, varscan2
- CLEC18C | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV100032013; called by muse, mutect2, varscan2
- CRYBG1 | c.4304A>G p.Y1435C | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV100954340; called by muse, mutect2, varscan2
- DCLRE1A | c.741G>C p.K247N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100800125; called by muse, mutect2, varscan2
- DHX15 | c.761A>G p.Y254C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391033; called by muse, mutect2, varscan2
- DNAH6 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV99403994; called by muse, mutect2
- DNAJC3 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1262426730, COSV65133542; called by muse, mutect2
- DPPA4 | c.409A>C p.K137Q | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV100169120; called by muse, mutect2, varscan2
- DPYSL5 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99981514, COSV99981534; called by muse, mutect2, varscan2
- DRD5 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.07); catalogued as rs776907638, COSV100431435; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EIF2B4 | c.235G>C p.E79Q (on ENST00000347454 / NM_001034116.2; = p.E78Q on NM_015636.3) | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV99277125; called by muse, mutect2, varscan2
- EP300 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.616); catalogued as COSV54347351, COSV99606956; called by muse, mutect2, varscan2
- EVC | c.1658A>T p.E553V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99380915; called by muse, mutect2, varscan2
- F9 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as CM940659, COSV99496163; called by muse, mutect2, varscan2
- FAAP100 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as COSV100585145; called by muse, mutect2, varscan2
- FAM114A2 | c.1247C>G p.T416S | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100697540; called by muse, mutect2
- FAM50A | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99340789; called by muse, mutect2, varscan2
- FAT4 | c.14537C>G p.S4846C | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100626805; called by muse, mutect2
- FMNL2 | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406257496, COSV99978570; called by muse, mutect2
- FRMD5 | c.1418A>C p.E473A | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV101296215; called by muse, mutect2, varscan2
- GMIP | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs1456134560, COSV52554305; called by muse, mutect2
- GPRC5A | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs763001828, COSV99185502; called by muse, mutect2, varscan2
- GTF3C1 | c.4866G>C p.L1622F | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV100648835; called by muse, mutect2, varscan2
- HNF4A | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV100290907; called by muse, mutect2, varscan2
- IL1R1 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99292274; called by muse, varscan2
- INO80D | c.3059C>G p.S1020C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as COSV101305757; called by muse, mutect2, varscan2
- KCTD8 | c.936C>A p.S312R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100759018; called by muse, mutect2
- KCTD8 | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.829); catalogued as rs372138598; called by muse, mutect2
- LAMC3 | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100735855; called by muse, mutect2, varscan2
- LCE2B | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 25/360 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.966); catalogued as COSV100909246; called by muse, mutect2
- LDB1 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.169); catalogued as rs1411383662, COSV100756290; called by muse, mutect2, varscan2
- LDB3 | c.1870G>C p.A624P | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879218802, COSV99554542; called by muse, mutect2, varscan2
- LIPE | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99733707; called by muse, mutect2, varscan2
- LRRC8D | c.404C>G p.T135R | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100486914; called by muse, mutect2
- MAML2 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101593908; called by muse, mutect2, varscan2
- MARK4 | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV99487738; called by muse, mutect2, varscan2
- MBTD1 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV100899036; called by muse, mutect2, varscan2
- MICAL3 | c.5492G>A p.R1831H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201337842; called by muse, mutect2, varscan2
- MYH3 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 27/205 reads (13%) | catalogued as COSV99877503; called by muse, mutect2, varscan2
- NCAPD3 | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 40/308 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV101592156; called by muse, mutect2, varscan2
- NCOR1 | c.6916G>A p.E2306K | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV99246231; called by muse, mutect2
- NINL | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV99624225; called by muse, mutect2, varscan2
- NIPBL | c.7188C>G p.Y2396* | Nonsense Mutation (SNP) | VAF 49/287 reads (17%) | catalogued as COSV99238162; called by muse, mutect2, varscan2
- NPR3 | c.613A>C p.S205R | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.772); catalogued as COSV99421860; called by muse, mutect2, varscan2
- NRXN1 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100452513; called by muse, mutect2, varscan2
- NUP155 | c.343G>C p.A115P (on ENST00000231498 / NM_153485.3; = p.A56P on NM_004298.4) | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99192107; called by muse, mutect2
- OR2J3 | c.474C>G p.N158K | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV101013529; called by muse, mutect2
- PARD6G | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100783269; called by muse, mutect2, varscan2
- PBDC1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1219444965, COSV64896262; called by muse, mutect2, varscan2
- PCDHB12 | c.1513T>C p.S505P | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as rs781797460, COSV99506515; called by muse, mutect2
- PDYN | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99452555; called by muse, mutect2, varscan2
- PEX5L | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as rs766854155, COSV99827601; called by muse, mutect2, varscan2
- PHACTR2 | c.1353C>A p.Y451* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99990802; called by muse, mutect2, varscan2
- PLXNB2 | c.2248G>A p.D750N | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs1332617247, COSV100833770; called by muse, mutect2, varscan2
- PPP1R3A | c.2815A>T p.T939S | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99491644; called by muse, mutect2
- PRICKLE2 | c.2418G>C p.R806S (on ENST00000295902; = p.R750S on NM_198859.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV99896411; called by muse, mutect2, varscan2
- PRMT3 | c.744C>A p.Y248* | Nonsense Mutation (SNP) | VAF 35/107 reads (33%) | catalogued as COSV100423534; called by muse, mutect2, varscan2
- RAB12 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs987543501, COSV100251410; called by muse, mutect2, varscan2
- RAI14 | c.568A>T p.M190L | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV99461364; called by muse, mutect2, varscan2
- RASGRF2 | c.3458A>G p.Y1153C | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428216; called by muse, mutect2, varscan2
- RIPK2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99609577; called by muse, mutect2, varscan2
- RUNDC3B | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99711766; called by muse, varscan2
- SEC23A | c.2159C>G p.S720* | Nonsense Mutation (SNP) | VAF 13/189 reads (7%) | catalogued as COSV100304928; called by muse, mutect2
- SEC23A | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.324); catalogued as COSV100304932; called by muse, mutect2, varscan2
- SGK3 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 22/288 reads (8%) | catalogued as COSV100616515, COSV61894770; called by muse, mutect2
- SH3GL3 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV100195532; called by muse, mutect2, varscan2
- SIDT1 | c.2207C>G p.S736C | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV53498972, COSV99332830; called by muse, mutect2
- SLC4A5 | c.3260G>A p.R1087K | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100697302; called by muse, mutect2, varscan2
- SLC8A1 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243850; called by muse, mutect2, varscan2
- SNRPA | c.57G>C p.E19D | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99698683; called by muse, mutect2
- SPTAN1 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.842); catalogued as COSV100823127; called by muse, mutect2
- SPTLC3 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV100982813; called by muse, mutect2, varscan2
- STX17 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99407796; called by muse, mutect2, varscan2
- SUPT20H | c.1556C>G p.S519C (on ENST00000350612 / NM_001014286.3; = p.S520C on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV100634481, COSV62247782; called by muse, mutect2, varscan2
- SYNE2 | c.13998G>C p.Q4666H | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as rs771593720, COSV59971452; called by muse, mutect2, varscan2
- THAP5 | c.1129G>A p.E377K (on ENST00000415914 / NM_001130475.3; = p.E335K on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100542735; called by muse, mutect2, varscan2
- TLR10 | c.419A>G p.N140S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV100457326; called by muse, mutect2
- TMF1 | c.2183C>G p.T728R | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs755851674, COSV101275381; called by muse, mutect2, varscan2
- TP53 | c.749_750del p.P250Hfs*13 | Frame Shift Del (DEL) | VAF 45/109 reads (41%) | catalogued as COSV52978598, COSV52980567, COSV53623927; called by mutect2, pindel, varscan2
- TSPOAP1 | c.3289G>C p.E1097Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV99269657; called by muse, mutect2, varscan2
- TTN | c.22561G>A p.E7521K (on ENST00000591111; = p.E6594K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | PolyPhen benign (0.16); catalogued as rs891050085, COSV100588437; called by muse, mutect2, varscan2
- TTPA | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV99478355; called by muse, mutect2
- TUT7 | c.3902T>G p.M1301R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99462208; called by muse, mutect2, varscan2
- TUT7 | c.3272C>T p.S1091L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV99462211; called by muse, mutect2
- USP7 | c.1645A>G p.R549G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV100783893; called by muse, mutect2
- USP8 | c.3080C>G p.S1027C | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); catalogued as COSV100208587; called by muse, mutect2
- UVRAG | c.1437G>C p.K479N | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV100637957; called by muse, mutect2
- VWA2 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV100073181; called by mutect2, varscan2
- VWF | c.8292C>G p.I2764M | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54618390, COSV99777598; called by muse, mutect2, varscan2
- WNK3 | c.2609G>T p.R870L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100670562; called by muse, mutect2, varscan2
- ZBTB34 | c.134C>A p.A45D | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100043501; called by muse, mutect2, varscan2
- ZFP42 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100478500; called by muse, mutect2
- ZNF134 | c.462C>A p.H154Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101270685; called by muse, mutect2, varscan2
- ZNF257 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749457994, COSV101447962; called by muse, mutect2
- ZNF319 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54623751; called by muse, mutect2, varscan2
- ZNF549 | c.1058G>A p.R353K (on ENST00000376233 / NM_001199295.2; = p.R340K on NM_153263.2) | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.881); catalogued as COSV53727494; called by muse, mutect2
- ZNF789 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100507731; called by muse, mutect2
- ADCY6 | c.2995_2997del p.N999del | In Frame Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- MAGEB6B | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL5 | c.820_831+7del p.X274_splice | Splice Site (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- ZNF750 | c.380del p.G127Dfs*239 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- ADAM9 | c.327T>C p.N109= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as rs1214320550, COSV101122208; called by muse, mutect2
- ANK3 | c.2670G>A p.K890= (on ENST00000280772 / NM_001320874.2; = p.K24= on NM_001149.3) | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as COSV99777593; called by muse, mutect2, varscan2
- ATP8A1 | c.1590G>A p.V530= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100044525; called by muse, mutect2
- BRWD3 | c.927G>A p.V309= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100955536; called by muse, mutect2, varscan2
- BTK | c.96G>A p.L32= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV100437209; called by muse, mutect2
- C2CD6 | c.288G>A p.E96= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV53794862, COSV53795239; called by muse, mutect2
- CEP350 | c.4905A>G p.R1635= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV100854194; called by muse, mutect2, varscan2
- DYNC2H1 | c.7087C>T p.L2363= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV100517036; called by muse, mutect2, varscan2
- EPG5 | c.2199G>A p.E733= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99956196; called by muse, mutect2, varscan2
- FAM71B | c.468C>G p.P156= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100261654; called by muse, mutect2
- FUNDC1 | c.450G>A p.L150= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100953598; called by muse, mutect2, varscan2
- GSTP1 | c.369G>T p.L123= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV101281999; called by muse, mutect2, varscan2
- HID1 | c.1158C>G p.L386= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100585905; called by muse, mutect2, varscan2
- HSPH1 | c.1326A>G p.L442= | Silent (SNP) | VAF 66/288 reads (23%) | catalogued as COSV100184591; called by muse, mutect2, varscan2
- IDH2 | c.204G>A p.E68= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV100342989; called by muse, mutect2, varscan2
- IRAK1 | c.723G>A p.L241= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV100317719; called by muse, mutect2, varscan2
- LAMC3 | c.4026G>T p.L1342= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100735854; called by muse, mutect2, varscan2
- LMTK2 | c.1776C>G p.L592= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV99805706; called by muse, mutect2, varscan2
- MME | c.792C>T p.I264= | Silent (SNP) | VAF 20/323 reads (6%) | catalogued as rs781570758, COSV100852126; called by muse, mutect2
- MMP28 | c.756C>G p.P252= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1555604949; called by muse, mutect2, varscan2
- NGFR | c.327C>T p.C109= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV50801868; called by muse, mutect2, varscan2
- OR2M7 | c.51C>A p.I17= | Silent (SNP) | VAF 11/280 reads (4%) | catalogued as COSV100522372; called by muse, mutect2
- OR51G2 | c.219G>A p.L73= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100431999; called by muse, mutect2, varscan2
- OR5R1 | c.123C>A p.G41= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs568499294, COSV100393184; called by muse, mutect2, varscan2
- PCDH9 | c.1050T>C p.D350= | Silent (SNP) | VAF 18/215 reads (8%) | catalogued as COSV100117251; called by muse, mutect2
- PCK1 | c.345C>T p.R115= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100099809; called by muse, mutect2, varscan2
- PLEKHG1 | c.2340C>T p.S780= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs779553877, COSV100651395; called by muse, mutect2, varscan2
- PRSS36 | c.843C>G p.T281= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99191212; called by muse, mutect2, varscan2
- RASA3 | c.1296G>A p.Q432= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV100479472; called by muse, mutect2, varscan2
- RFX4 | c.1161C>G p.L387= (on ENST00000392842 / NM_213594.3; = p.L293= on NM_032491.6) | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as COSV99985196; called by muse, mutect2
- RP1 | c.2469T>C p.F823= | Silent (SNP) | VAF 7/160 reads (4%) | catalogued as COSV99605728; called by muse, mutect2
- SEC14L3 | c.1059C>G p.L353= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV99306830; called by muse, mutect2
- SIPA1L2 | c.1245G>A p.E415= | Silent (SNP) | VAF 14/292 reads (5%) | catalogued as COSV99476813; called by muse, mutect2
- SULT1B1 | c.672C>A p.I224= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100150031; called by muse, mutect2, varscan2
- TEKT5 | c.1194G>C p.R398= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as COSV99295712; called by muse, mutect2
- TTLL7 | c.1200C>G p.L400= | Silent (SNP) | VAF 10/165 reads (6%) | catalogued as rs1308010072, COSV99551596; called by muse, mutect2
- UBXN6 | c.1302G>T p.L434= | Silent (SNP) | VAF 9/204 reads (4%) | catalogued as COSV100010653; called by muse, mutect2
- ZBTB37 | c.771G>A p.E257= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100774492; called by muse, mutect2, varscan2
- ZFAT | c.741C>T p.Y247= | Silent (SNP) | VAF 46/172 reads (27%) | catalogued as rs767588874, COSV64737523; called by muse, mutect2, varscan2
- ZNF415 | c.117C>T p.Y39= | Silent (SNP) | VAF 60/229 reads (26%) | catalogued as rs1257485910, COSV99701081; called by muse, mutect2, varscan2
- ZSCAN29 | c.1551C>T p.T517= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV101212138; called by muse, mutect2, varscan2
- ANKRD33 | c.664+38G>T | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100001051; called by muse, mutect2, varscan2
- CCNQP1 | n.477G>T | RNA (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- IKBIP | c.297+8163A>T | Intron (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100141627; called by muse, mutect2, varscan2
- PDLIM3 | c.93+10244G>C | Intron (SNP) | VAF 22/224 reads (10%) | catalogued as COSV99507316; called by muse, mutect2
- TACC1 | c.1392-1311G>A | Intron (SNP) | VAF 11/264 reads (4%) | catalogued as COSV99392708; called by muse, mutect2
